Surgical pathology report (de-identified scan), TCGA case TCGA-CU-A3QU, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site UNC, specimen TCGA-CU-A3QU-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATH

Case Number:

Diagnosis:

FSA: Ureter margin, left, biopsy

- No tumor identified

FSB: Ureter margin, right, biopsy

- No tumor identified

C: Lymph nodes, common iliac, dissection

- No metastatic carcinoma identified (0/3)

D: Lymph nodes, presacral, dissection

- No metastatic carcinoma identified (0/6)

E: Lymph nodes, right external iliac, dissection

- Metastatic urothelial carcinoma (1/7)

- Size of lymph node metastasis: 1.5 mm

- Extracapsular extension: not identified

F: Lymph nodes, right obturator, dissection

- No metastatic carcinoma identified (0/12)

G: Lymph nodes, left common iliac, dissection

- No metastatic carcinoma identified (0/5)

H: Lymph nodes, left external iliac, dissection

- No metastatic carcinoma identified (0/12)

I: Lymph nodes, left obturator, dissection

- No metastatic carcinoma identified (0/9)

J: Ureter, right proximal, excision

- No carcinoma identified

K: Bladder and prostate, cystoprostatectomy

Bladder:

Tumor histologic type: Invasive urothelial carcinoma

Tumor histologic grade (WHO classification): High grade

Macroscopic tumor size (greatest dimension): 7.5 cm

Microscopic extent of invasion: Into deep (outer half) muscularis propria

ICD-O-3
carcinoma, urothelial, NOS
8120/3
Site: bladder, NOS
C67.9
3-30-12 CD

[page 2 of 6]
Tumor site/focality of tumor: Unifocal

Angiolymphatic space invasion: Present

Associated epithelial lesions: Papillary urothelial carcinoma, high grade(K3)

Ureters: Not involved; right UVJ involved (K11); left UVJ not involved

Histologic assessment of surgical margins:

Ureter, left: negative (specimen A)

Ureter, right: negative (specimen B)

Urethra: negative

Paravesicular soft tissue: negative

Other significant findings: Prostate and seminal vesicles: no HGPIN or invasive carcinoma identified

Lymph nodes:

- All separately submitted (specimens C-I): metastatic urothelial carcinoma in 1/54 total

Size and location of largest lymph node metastasis: Right external iliac lymph node, 1.5 mm metastasis (E1)

Extracapsular extension: Not identified

Diagnoses of other organs or structures: chronic and acute prostatitis and urethritis

AJCC Stage (Bladder primary): pT2b pN1 pMx

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

L: Ureter, left proximal, biopsy

- No carcinoma identified

Intraoperative Consult Diagnosis:

Frozen section consultation was requested.

FSA1: Ureter, left, margin, biopsy

- No tumor seen

FSB1: Ureter, right, margin, biopsy

[page 3 of 6]
- No tumor seen

Clinical History:

-year-old with pathologic T1, but clinical T3 N1 based upon imaging papillary urothelial carcinoma of the bladder. There has been no neoadjuvant therapy.

Gross Description:

Received are eleven appropriately labeled containers. Specimens A and B are received fresh for frozen section.

Container A is additionally labeled "left ureteral margin." The specimen is a 6 x 6 x 3 mm white/tan tube of soft tissue that is entirely submitted as FSA1,

Container B is additionally labeled "right ureteral margin." The specimen is an 8 x 8 x 2 mm white/tan tube of soft tissue (dilated lumen) that is entirely submitted as FSB1,

Container C is additionally labeled "right common iliac lymph node." It holds a 4 x 2.7 x 1.2 cm aggregate of fibroadipose tissue fragments.

Block summary:

C1 - one lymph node candidate, bisected
C2 - one elongated lymph node candidate, halved
C3-C4 - remainder of specimen,

Container D is additionally labeled "presacral lymph node." The container holds a 3.5 x 1.6 x 0.9 cm fibroadipose soft tissue fragment.

Block summary:

D1 - one lymph node candidate, bisected
D2 - one lymph node candidate
D3 - remainder of specimen,

Container E is additionally labeled "right external iliac nodes." The container holds a 6 x 5 x 1 cm aggregate of fibroadipose tissue fragments.

Block summary:

E1 - one 2.1 cm lymph node, trisected
E2 - one lymph node candidate, bisected
E3 - one 1.5 cm lymph node, bisected
E4 - one 1.6 cm lymph node, bisected
E5-E7 - one 3.5 cm lymph node
E8-E11 - additional fibroadipose tissue with possible lymph node candidate

[page 4 of 6]
Fibrofatty tissue remains in the container.

Container F is additionally labeled "right obturator lymph nodes." The container holds a 6.5 x 5.5 x 1.2 cm aggregate of fibroadipose tissue fragments.

Block summary:

F1 - one lymph node candidate, bisected

F2 - multiple lymph node candidates

F3 - multiple lymph node candidates

F4-F6 - representative sections of one large elongated fatty replaced 5.5 cm

lymph node

F7, F8 - additional fibroadipose tissue with possible lymph node candidate

Fatty tissue remains in the container.

Container G is additionally labeled "left common iliac lymph node." The container holds a 3.5 x 3.2 x 1.0 cm aggregate of fibroadipose tissue fragments.

Block summary:

G1 - one lymph node candidate, bisected

G2, G3 - fibroadipose tissue with multiple possible lymph node candidates

Fatty tissue remains in the container.

Container H is additionally labeled "left external iliac lymph nodes." The container holds a 5 x 4.9 x 1.3 cm aggregate of fibroadipose tissue fragments.

Block summary:

H1, H2 - one 3.1 cm lymph node, bisected

H3 - one lymph node candidate, bisected

H4 - one lymph node candidate, bisected

H5 - one lymph node candidate, bisected

H6-H8 - multiple lymph node candidates each cassette

Fatty tissue remains in the container.

Container I is additionally labeled "left obturator lymph nodes." The container holds a 4.8 x 3.1 x 1.4 cm aggregate of fibroadipose tissue fragments.

Block summary:

I1 - one lymph node candidate, bisected

I2, I3 - one 3 cm lymph node, bisected

I4, I5 - remainder of specimen,

Container J is additionally labeled "right proximal ureter." The

[page 5 of 6]
container holds a 2 x 1.1 cm white/tan soft tissue fragment with a patent lumen and stitch and clips on one side. The specimen is sectioned perpendicular to the lumen. Sectioning closest to the stitch, encases the margin, and is inked blue. The specimen is submitted in block J1,

Container K is additionally labeled "bladder and prostate." The container holds a cystoprostatectomy specimen with overall measurements of 4.5 x 11 x 10 cm. The prostate measures 4.3 cm superior to inferior, 2.7 cm anterior to posterior, and 4.3 cm side to side. Inking: right perivesical soft tissue=blue, left perivesical soft tissue=black, distal urethral margin=yellow. The entire bladder mucosa is involved by a large 4.7 x 6.3 x 7.5 cm white/tan papillary friable white/tan mass with a shaggy surface filling the lumen of the bladder. On cross section, the thickness of the bladder wall from the top of the tumor to inked soft tissue margin is 4.7 cm. The mass invades into the muscularis propria and is 2.0 cm from the inked soft tissue surface at the deepest point of invasion in right bladder sidewall

Block summary:

- K1 - distal urethral margin, en face
- K2,K3 - representative sections of the superficial portion of the tumor
- K4 - bladder dome, representative sections
- K5 - posterior bladder midline
- K6 - posterior bladder midline
- K7 - bladder trigone midline
- K8 - prostatic urethra, posterior midline
- K9,K10 - right bladder sidewall, full thickness section at deepest invasion, section bisected
- K9 superficial
- K10 deep
- K11 - right UVJ
- K12 - right ureter and vas deferens margins in this specimen, en face
- K13-K16 - representative right prostate and seminal vesicle
- K17 - left ureter and vas deferens margin in this specimen
- K18 - left bladder sidewall
- K19,K20 - left UVJ
- K21,K22 - tumor in relation to left prostate lobe
- K23-K25 - representative left prostate and left seminal vesicle

[page 6 of 6]
Container L is additionally labeled "left proximal ureter." The container holds a 0.9 x 0.2 cm white/tan soft tissue fragment with lumen with a clip. The specimen is bisected to aide in orientation and totally submitted in block L1,

Light Microscopy:

The frozen section diagnoses are confirmed. Invasive carcinoma is identified in blocks K2-5, K9, K11, and K21. No prostatic invasion is noted. No prostatic carcinoma is noted.

Source: NCI Genomic Data Commons file d785d5a3-ea56-404b-8b2e-5f2e35e921de (TCGA-CU-A3QU.3197D149-9CF0-4644-B192-F7BB6028AF45.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).